Gene-level copy-number profile of tumor specimen TCGA-BT-A3PH-01A from TCGA case TCGA-BT-A3PH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.7 years (28,030 days).
Specimen TCGA-BT-A3PH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e8e60f2e-8d6b-4b02-bea2-63397a0a96e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A3PH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8030f4fa-8fc6-41cd-b8a9-e4c73808beef

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 2: 7,463; copy number 3: 13,962; copy number 4: 32,495; copy number 5: 4,326; copy number 6: 760; copy number 7: 319; copy number 8: 242; copy number 10: 163; copy number 11: 17; copy number 12: 13; copy number 15: 3; copy number 17: 21; copy number 24: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A3PH-01A-11D-A21Y-01): tumor purity 0.83, ploidy 3.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:190,607,660–191,847,088, 22 genes: AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2.
- chr2:191,881,182–191,882,205, 1 gene: DNAJB1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 226 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,931,739–161,141,336, 17 genes, copy number 11: AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1.
- chr2:134,119,983–135,531,218, 15 genes, copy number 15–24 (within-gene range 2–24): MGAT5, RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3.
- chr11:66,070,272–70,436,584, 190 genes, copy number 10–17 (within-gene range 3–17) (broad region; genes not listed).
- chr11:70,477,277–70,647,562, 4 genes, copy number 12: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
